Somatic mutation profile of tumor specimen C3L-05908-54 (aliquot CPT0326900002) from CPTAC case C3L-05908, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.3 years (23,471 days).
Specimen C3L-05908-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4015a403-e289-471f-bb2e-e26c159b5218.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05908-50 (Buccal Cell Normal), aliquot CPT0326940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b545d2-974b-436c-a73c-9a9b31c75a0f

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 13/233 reads (6%) | catalogued as COSV53311244; called by muse, mutect2
- CELSR1 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL6ST | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID3C | c.55T>C p.L19= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2
- CACNA1A | c.3447C>T p.I1149= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs781300443, COSV100802539, COSV64202829; called by muse, mutect2, varscan2
